Somatic mutation profile of tumor specimen MP2PRT-PASKTV-TMP1-A (aliquot MP2PRT-PASKTV-TMP1-A-1-0-D-A81X-36) from MP2PRT case MP2PRT-PASKTV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,366 days).
Specimen MP2PRT-PASKTV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd549830-df99-46a9-bb79-d6948d1e3d10.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASKTV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASKTV-NB1-A-1-0-D-A81X-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/957e92b4-a70d-46f5-9c05-d962171f6cd6

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, Silent 7, Nonsense Mutation 1, In Frame Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 63/357 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BMT2 | c.355G>C p.D119H | Missense Mutation (SNP) | VAF 46/351 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.196); catalogued as COSV51776123; called by muse, mutect2, varscan2
- FUT4 | c.604G>A p.D202N | Missense Mutation (SNP) | VAF 75/731 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.035); catalogued as rs984644159, COSV62469209, COSV62469259, COSV62470017; called by muse, mutect2, varscan2
- GSE1 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 155/639 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as rs200986327; called by muse, mutect2, varscan2
- KLHL1 | c.28G>A p.D10N | Missense Mutation (SNP) | VAF 39/701 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.683); catalogued as rs753112360, COSV64766783; called by muse, mutect2
- MCOLN1 | c.599G>A p.R200Q | Missense Mutation (SNP) | VAF 147/402 reads (37%) | SIFT tolerated (0.34); PolyPhen benign (0.347); catalogued as rs779790863; called by muse, mutect2, varscan2
- PARD3B | c.2617G>A p.G873S (on ENST00000406610 / NM_001302769.2; = p.G804S on NM_057177.7) | Missense Mutation (SNP) | VAF 42/562 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs764241724; called by muse, mutect2
- PCNT | c.5284G>A p.E1762K | Missense Mutation (SNP) | VAF 87/626 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.097); catalogued as rs367926503; called by muse, mutect2, varscan2
- POLRMT | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 42/422 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1339218084, COSV73933205; called by muse, mutect2
- DSCAML1 | c.3340G>A p.D1114N (on ENST00000321322; = p.D1054N on NM_020693.4) | Missense Mutation (SNP) | VAF 48/464 reads (10%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- DST | c.16039C>G p.Q5347E (on ENST00000361203 / NM_001374722.1; = p.Q2935E on NM_015548.5) | Missense Mutation (SNP) | VAF 80/405 reads (20%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- IGKV1D-8 | c.351_352insTTTCC | In Frame Ins (INS) | VAF 34/78 reads (44%) | called by mutect2, pindel, varscan2
- MZF1 | c.1885G>A p.E629K | Missense Mutation (SNP) | VAF 66/981 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.015); called by muse, mutect2
- NUTM2D | c.1846C>T p.H616Y | Missense Mutation (SNP) | VAF 206/1174 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- POLG | c.860C>T p.S287F | Missense Mutation (SNP) | VAF 10/260 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- THNSL1 | c.528G>T p.Q176H | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.011); called by muse, mutect2
- TRIM33 | c.1780C>T p.Q594* | Nonsense Mutation (SNP) | VAF 17/509 reads (3%) | called by muse, mutect2
- XAB2 | c.534G>C p.E178D | Missense Mutation (SNP) | VAF 17/384 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.055); called by muse, mutect2
- HBZ | c.297C>T p.F99= | Silent (SNP) | VAF 10/222 reads (5%) | called by muse, mutect2
- LRFN3 | c.408C>G p.L136= | Silent (SNP) | VAF 32/728 reads (4%) | called by muse, mutect2
- LRFN3 | c.489C>G p.L163= | Silent (SNP) | VAF 38/702 reads (5%) | called by muse, mutect2
- MROH9 | c.1182G>A p.L394= | Silent (SNP) | VAF 49/176 reads (28%) | catalogued as rs781084958; called by muse, mutect2, varscan2
- NXPE1 | c.1017G>A p.K339= (on ENST00000424269; = p.K197= on NM_152315.5) | Silent (SNP) | VAF 17/336 reads (5%) | called by muse, mutect2
- OR10AG1 | c.201C>T p.I67= | Silent (SNP) | VAF 50/219 reads (23%) | catalogued as COSV100399989, COSV56634499; called by muse, mutect2, varscan2
- VCX | c.342G>C p.L114= | Silent (SNP) | VAF 40/306 reads (13%) | called by muse, varscan2
- MYADM | chr19:53874192 C>T | 3'Flank (SNP) | VAF 101/508 reads (20%) | called by muse, mutect2, varscan2
